Somatic mutation profile of tumor specimen ALCH-ABE5-TTP1-A (aliquot ALCH-ABE5-TTP1-A-1-0-D-A486-36) from ALCHEMIST case ALCH-ABE5, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 44.9 years (16,386 days).
Specimen ALCH-ABE5-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a21d0d1f-cec8-4c65-b266-c552babb88e0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ABE5-NB1-A (Blood Derived Normal), aliquot ALCH-ABE5-NB1-A-1-0-D-A486-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e530cc1d-fae5-4592-8d00-8f04d0438b8b

The open-access MAF lists 22 somatic variants for this specimen: 18 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 14, Silent 4, Frame Shift Del 2, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDC14B | c.1492C>T p.R498C (on ENST00000375241 / NM_033331.4; = p.R459C on NM_003671.5) | Missense Mutation (SNP) | VAF 30/306 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs765782765, COSV55786426; called by muse, mutect2
- DAGLA | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.296); catalogued as COSV57193778, COSV57197770; called by muse, mutect2, varscan2
- MAPKAPK5 | c.1248_1251del p.N416Kfs*2 (on ENST00000551404 / NM_139078.3; = p.N414Kfs*2 on NM_003668.4 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 106/450 reads (24%) | catalogued as rs1422293510; called by pindel, varscan2
- NYNRIN | c.4298G>A p.R1433Q | Missense Mutation (SNP) | VAF 67/317 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.669); catalogued as rs752986848; called by muse, mutect2, varscan2
- PHKA2 | c.1411A>G p.I471V | Missense Mutation (SNP) | VAF 220/956 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.206); catalogued as rs779157238, COSV66056140, COSV66056999; called by muse, mutect2, varscan2
- WNK1 | c.6212A>G p.D2071G (on ENST00000315939 / NM_018979.4; = p.D1823G on NM_014823.3) | Missense Mutation (SNP) | VAF 22/183 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as rs1295478510; called by muse, mutect2, varscan2
- ZNRF4 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 42/147 reads (29%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.198); catalogued as rs201511283; called by muse, mutect2, varscan2
- ADAM10 | c.2062C>A p.L688M | Missense Mutation (SNP) | VAF 24/726 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2
- CCDC88A | c.664C>T p.H222Y | Missense Mutation (SNP) | VAF 30/338 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.317); called by muse, mutect2
- KREMEN2 | c.361A>C p.M121L | Missense Mutation (SNP) | VAF 53/261 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- NFKBIE | c.258_272del p.L87_P91del | In Frame Del (DEL) | VAF 21/93 reads (23%) | called by mutect2, pindel, varscan2
- PARP1 | c.420dup p.K141Qfs*15 | Frame Shift Ins (INS) | VAF 154/718 reads (21%) | called by mutect2, pindel, varscan2
- PIGP | c.200C>T p.S67F (on ENST00000464265 / NM_153681.2; = p.S17F on NM_016430.4) | Missense Mutation (SNP) | VAF 32/438 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); called by muse, mutect2
- PLEKHM3 | c.347C>T p.T116I | Missense Mutation (SNP) | VAF 47/717 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.655); called by muse, mutect2
- PPM1B | c.808A>C p.N270H | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.018); called by muse, mutect2
- SETD2 | c.780_781del p.N261* | Frame Shift Del (DEL) | VAF 45/171 reads (26%) | called by mutect2, pindel, varscan2
- TLE1 | c.952A>T p.S318C | Missense Mutation (SNP) | VAF 71/352 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TRIM10 | c.1390G>T p.V464F | Missense Mutation (SNP) | VAF 23/176 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- ANKRD31 | c.4851A>G p.R1617= | Silent (SNP) | VAF 28/124 reads (23%) | called by muse, mutect2, varscan2
- NYNRIN | c.4299G>T p.R1433= | Silent (SNP) | VAF 70/319 reads (22%) | catalogued as COSV101230623; called by muse, mutect2, varscan2
- POPDC2 | c.99C>T p.A33= | Silent (SNP) | VAF 53/464 reads (11%) | called by muse, mutect2, varscan2
- PSG4 | c.837C>T p.S279= | Silent (SNP) | VAF 110/915 reads (12%) | called by muse, mutect2, varscan2
